Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8E2, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8E2-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, tubular 8211/3
Site: Body of stomach C16.2
JW 11/23/13

Collect date
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "8p lymph node":
Lymph node uninvolved by neoplasia (0/1).

2 - "Esophageal margin":
Uninvolved by neoplasia.

3 - "Stomach + omentum":
Adenocarcinoma:
Histological pattern observed: tubular
Histological grade:
II - moderately differentiated
Greatest dimension of the tumor: 7.5 cm
Ulceration: Present
Involvement of:
Mucosa
Muscularis mucosa
Submucosa
Muscular own
Adjacent adipose tissue

Type of tumor invasion: spiculated
Inflammatory reaction: Moderate
Tumor implantation in peri-visceral adipose tissue: Not detected
Proximal margin. uninvolved
Distal margin. uninvolved
Radial margin: uninvolved
Neural infiltration: Not detected
Lymphatic vascular invasion: Present
Blood vascular invasion: Not detected
Lymph Nodes:
4 involved by neoplasia among 15 dissected (4/15)
Great omentum: uninvolved by neoplasia
Distribution of lymph nodes:
Lesser curvature: 4/5
Large curvature: 0/9.

Er. v1a	11/10/2013	Yes	No
TIPIA Discrepancy			✓

Source: NCI Genomic Data Commons file 8ec624cb-d5d0-4bc7-9d0c-d004aaa8aabd (TCGA-VQ-A8E2.1855A994-FBC6-421A-8C5D-1F1656A994ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).